Gene-level copy-number profile of tumor specimen TCGA-XM-A8RF-01A from TCGA case TCGA-XM-A8RF, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 84.6 years (30,893 days).
Specimen TCGA-XM-A8RF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.181a1067-45f3-447b-b775-f96b843a63b5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XM-A8RF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3454161a-6145-4fe2-b5cb-7f689d558fee

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,531; copy number 2: 56,069; copy number 3: 2,215.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XM-A8RF-01A-11D-A422-01): tumor purity 0.75, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,531. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
